Somatic mutation profile of tumor specimen TCGA-AA-A02Y-01A (aliquot TCGA-AA-A02Y-01A-43W-A096-10) from TCGA case TCGA-AA-A02Y, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 73.2 years (26,724 days).
Specimen TCGA-AA-A02Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c793446b-09ed-4f6e-b373-8c8c201fa6e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02Y-10A (Blood Derived Normal), aliquot TCGA-AA-A02Y-10A-01W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c2dad8d-5d39-459e-9adc-abbb7d2d304a

The open-access MAF lists 117 somatic variants for this specimen: 97 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 18, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 115/229 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 51/197 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA12 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV99790339; called by muse, mutect2, varscan2
- ABCB1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 117/432 reads (27%) | catalogued as rs1373964332, COSV55949025; called by muse, mutect2, varscan2
- ACACB | c.3713T>G p.L1238R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); catalogued as COSV100623005; called by muse, mutect2, varscan2
- ADAMTS9 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406750469, COSV99899612; called by muse, mutect2, varscan2
- AFF2 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV53993370, COSV99663202; called by muse, mutect2, varscan2
- AFF3 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 268/734 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs145368049, COSV100417858; called by muse, mutect2, varscan2
- AKAP6 | c.4612C>T p.R1538C | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs369118703, COSV99801558; called by muse, mutect2, varscan2
- ALG10B | c.1411T>G p.F471V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100439923; called by muse, mutect2, varscan2
- APOE | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52985751; called by muse, mutect2, varscan2
- ARHGEF15 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100729975, COSV100730060; called by muse, mutect2, varscan2
- ASTN2 | c.3866G>A p.R1289H (on ENST00000313400 / NM_001365069.1; = p.R1238H on NM_014010.5) | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs139072409; called by muse, mutect2, varscan2
- ATM | c.8161G>A p.D2721N | Missense Mutation (SNP) | VAF 104/297 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM149284, COSV53726516, COSV53771356; called by muse, mutect2, varscan2
- ATP1A2 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767892; called by muse, mutect2, varscan2
- CD63 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs11574657; called by muse, mutect2, varscan2
- CDH11 | c.1556A>G p.D519G | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99218728; called by muse, mutect2, varscan2
- CFAP61 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as rs760689597, COSV55620168, COSV55632747; called by muse, mutect2, varscan2
- CFH | c.3355G>A p.D1119N | Missense Mutation (SNP) | VAF 224/404 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as CM131604, COSV100809701; called by muse, mutect2, varscan2
- CHRD | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs199856196, COSV52605712; called by muse, mutect2, varscan2
- CNOT1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs371890421, COSV100408635; called by muse, mutect2, varscan2
- CPA5 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100812365; called by muse, mutect2, varscan2
- CTNNA3 | c.2386C>A p.L796I | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV65525500; called by muse, mutect2, varscan2
- EIF2AK3 | c.1459A>T p.R487W | Missense Mutation (SNP) | VAF 62/1142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100303827; called by muse, mutect2
- EXD3 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV59808510, COSV59808802; called by muse, mutect2, varscan2
- FAM135B | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52752592; called by muse, mutect2, varscan2
- FBXO10 | c.2009T>A p.L670Q | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV52833559; called by muse, mutect2, varscan2
- FERD3L | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99284972; called by muse, mutect2, varscan2
- FUNDC1 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 527/1163 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV65181548; called by muse, mutect2, varscan2
- GCNT1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs369681886; called by muse, mutect2, varscan2
- GJA10 | c.1622T>G p.F541C | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV101005371; called by muse, mutect2, varscan2
- GRIA1 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as COSV99600420; called by muse, mutect2, varscan2
- GRM7 | c.1175-2A>G p.X392_splice | Splice Site (SNP) | VAF 107/321 reads (33%) | catalogued as COSV100736958; called by muse, mutect2, varscan2
- HECW2 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99647486; called by muse, varscan2
- HIP1R | c.3124C>T p.Q1042* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV53442236; called by muse, mutect2, varscan2
- HS3ST4 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100501730; called by muse, mutect2, varscan2
- HTR2C | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs782814171, COSV52202906; called by muse, mutect2, varscan2
- ICE1 | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 117/309 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV56826994; called by muse, mutect2, varscan2
- IFT80 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV100424767, COSV100424833; called by muse, varscan2
- INTS6L | c.1059+1G>C p.X353_splice | Splice Site (SNP) | VAF 142/298 reads (48%) | catalogued as COSV66084690; called by muse, mutect2, varscan2
- ITPR1 | c.4804G>A p.E1602K (on ENST00000354582; = p.E1587K on NM_002222.7) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100231693; called by muse, mutect2, varscan2
- JAKMIP2 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 140/317 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751197088, COSV99508508; called by muse, mutect2, varscan2
- LRP1B | c.11765G>T p.R3922I | Missense Mutation (SNP) | VAF 204/586 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1167904406, COSV101257779, COSV67222411; called by muse, mutect2, varscan2
- MAGEB4 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs767138317, COSV64397128; called by muse, mutect2, varscan2
- MCF2L2 | c.1789T>G p.F597V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100192836; called by muse, mutect2, varscan2
- MEIS1 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV55488251, COSV99715342; called by muse, mutect2, varscan2
- MLPH | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs568517279, COSV52825709; called by muse, mutect2, varscan2
- MPP4 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 115/329 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs369705514, COSV59632001; called by muse, mutect2, varscan2
- MTUS2 | c.3634C>T p.R1212C (on ENST00000612955 / NM_001366650.1; = p.R191C on NM_015233.6) | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373897999; called by muse, mutect2, varscan2
- MXRA5 | c.3400C>A p.Q1134K | Missense Mutation (SNP) | VAF 106/246 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99477403; called by muse, mutect2, varscan2
- NELL1 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as COSV54236708, COSV54263958; called by muse, mutect2
- NOBOX | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs1563129022, COSV56193251, COSV56194121; called by muse, mutect2, varscan2
- NPAP1 | c.1794C>A p.S598R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV100275533; called by muse, mutect2, varscan2
- OR5D16 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as rs1297589017, COSV65722217; called by muse, mutect2, varscan2
- OSBP | c.1916A>C p.H639P | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99803046; called by muse, mutect2, varscan2
- PCDHB10 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs782184579, COSV53376409, COSV53383976; called by muse, mutect2, varscan2
- PCDHGA6 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.014); catalogued as rs777443061, COSV54054575; called by muse, mutect2, varscan2
- PCLO | c.4586G>T p.R1529L | Missense Mutation (SNP) | VAF 393/756 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV61629977, COSV61641483; called by muse, mutect2, varscan2
- PDIA5 | c.242G>T p.C81F | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1487610441, COSV60249862; called by muse, mutect2, varscan2
- PEG3 | c.983C>A p.S328* | Nonsense Mutation (SNP) | VAF 57/155 reads (37%) | catalogued as COSV55624252, COSV55636762; called by muse, mutect2, varscan2
- PLAAT5 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs144730159; called by muse, mutect2, varscan2
- PLEKHG1 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243766874, COSV62046970; called by muse, mutect2, varscan2
- POU4F2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs772758327, COSV55585038; called by muse, varscan2
- PUS7L | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 237/1045 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100786554; called by muse, mutect2, varscan2
- ROBO2 | c.3686A>C p.E1229A | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV59915892; called by muse, mutect2, varscan2
- RPE | c.559G>A p.A187T (on ENST00000359429 / NM_001318926.1; = p.A137T on NM_006916.2) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV55993211; called by muse, mutect2, varscan2
- RXFP4 | c.833C>G p.P278R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV58146269; called by muse, mutect2, varscan2
- RYR2 | c.7696C>T p.R2566W | Missense Mutation (SNP) | VAF 151/545 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773475551, COSV100770955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCEL | c.2009G>T p.R670I (on ENST00000349847 / NM_144777.3; = p.R650I on NM_003843.4) | Missense Mutation (SNP) | VAF 144/654 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV62993775; called by muse, mutect2
- SCG2 | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 182/487 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.061); catalogued as COSV59540543; called by muse, mutect2, varscan2
- SF1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as rs111552365, COSV57114945; called by muse, mutect2, varscan2
- SMCHD1 | c.1281C>G p.I427M | Missense Mutation (SNP) | VAF 163/412 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1210087689, COSV99861874, COSV99861995; called by muse, mutect2, varscan2
- SPDYA | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.444); catalogued as rs753354043, COSV60258273; called by muse, mutect2, varscan2
- STK10 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs375820809; called by muse, mutect2, varscan2
- STK31 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 125/426 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as COSV100669512; called by muse, mutect2, varscan2
- STPG2 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.019); catalogued as COSV99759761; called by muse, mutect2, varscan2
- TDRD3 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1385421031, COSV52158105; called by muse, mutect2, varscan2
- TDRD9 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 245/651 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100175239; called by muse, mutect2, varscan2
- TFR2 | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs987041183, COSV99774556; called by muse, mutect2, varscan2
- TNRC6B | c.2126G>A p.W709* | Nonsense Mutation (SNP) | VAF 32/93 reads (34%) | catalogued as COSV57298835; called by muse, mutect2, varscan2
- TRAF5 | c.491G>T p.R164L | Missense Mutation (SNP) | VAF 77/311 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs765593941, COSV54822998, COSV54824019; called by muse, mutect2, varscan2
- TRIO | c.9218G>A p.R3073H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59990654; called by muse, varscan2
- TRPS1 | c.1070C>A p.T357N (on ENST00000220888 / NM_001330599.2; = p.T370N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/369 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV99631628; called by muse, mutect2, varscan2
- TTN | c.95087C>A p.A31696D (on ENST00000591111; = p.A24272D on NM_003319.4) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | PolyPhen benign (0.306); catalogued as COSV100617361; called by muse, mutect2, varscan2
- UPF2 | c.2111G>T p.C704F | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100707309; called by muse, mutect2, varscan2
- USP13 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as rs61760204, COSV55864769; called by muse, mutect2, varscan2
- UTRN | c.8857G>T p.V2953L | Missense Mutation (SNP) | VAF 207/516 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100837865; called by muse, mutect2, varscan2
- VIT | c.817G>T p.E273* (on ENST00000389975 / NM_001177969.1; = p.E288* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 84/212 reads (40%) | catalogued as COSV101007459; called by muse, mutect2, varscan2
- VRTN | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs753558328, COSV99832292; called by muse, mutect2, varscan2
- WDR4 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1046993067, COSV57734035; called by muse, mutect2, varscan2
- XG | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766062680, COSV66985624; called by muse, mutect2, varscan2
- ZDHHC15 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 186/385 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs763305438, COSV100973614, COSV64902097; called by muse, mutect2, varscan2
- ZNF620 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as rs138858148; called by muse, mutect2, varscan2
- FLT1 | c.2925_2926del p.L977Efs*2 | Frame Shift Del (DEL) | VAF 72/257 reads (28%) | called by mutect2, pindel, varscan2
- HIRA | c.1950_1951del p.R651Sfs*54 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | called by pindel, varscan2
- KIAA1614 | c.2060del p.N687Mfs*3 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- XRCC4 | c.382del p.C128Vfs*25 | Frame Shift Del (DEL) | VAF 59/216 reads (27%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11631C>T p.N3877= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs374031988; called by muse, mutect2, varscan2
- ADAMTS2 | c.2508C>A p.I836= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52378980; called by muse, varscan2
- CCDC40 | c.2103C>T p.D701= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs773201310, COSV66475768; called by muse, mutect2, varscan2
- CD300LG | c.84C>T p.F28= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs775408229, COSV53223109; called by muse, mutect2, varscan2
- COL6A6 | c.4407C>T p.N1469= | Silent (SNP) | VAF 226/581 reads (39%) | catalogued as rs774517921, COSV62016806; called by muse, mutect2, varscan2
- CYP4F8 | c.1356G>A p.K452= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV57853984, COSV57854355; called by muse, mutect2, varscan2
- FAT3 | c.11379G>A p.P3793= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs779979255, COSV53124644; called by muse, mutect2, varscan2
- GALP | c.240T>C p.P80= | Silent (SNP) | VAF 38/389 reads (10%) | catalogued as COSV100627986; called by muse, mutect2
- KCNG4 | c.360C>T p.F120= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1212818723, COSV57584306; called by muse, mutect2, varscan2
- PHACTR2 | c.450G>A p.P150= | Silent (SNP) | VAF 68/181 reads (38%) | catalogued as rs200897868, COSV59855440; called by muse, mutect2, varscan2
- PLEKHO1 | c.159C>G p.L53= | Silent (SNP) | VAF 94/141 reads (67%) | catalogued as COSV50310477; called by muse, mutect2, varscan2
- SCML2 | c.444A>G p.T148= | Silent (SNP) | VAF 497/603 reads (82%) | catalogued as COSV52622165; called by muse, mutect2, varscan2
- SFMBT2 | c.129C>A p.G43= | Silent (SNP) | VAF 58/157 reads (37%) | catalogued as COSV62811127; called by muse, mutect2, varscan2
- SLC4A4 | c.2130G>T p.L710= (on ENST00000264485 / NM_001098484.3; = p.L666= on NM_003759.4) | Silent (SNP) | VAF 102/343 reads (30%) | catalogued as COSV52627044; called by muse, mutect2, varscan2
- SMPD3 | c.1137C>T p.H379= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs746970417, COSV54710591; called by muse, mutect2, varscan2
- TANC2 | c.5955C>T p.F1985= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs371666530; called by muse, mutect2, varscan2
- TTLL11 | c.1086G>A p.G362= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58647631; called by muse, mutect2, varscan2
- ZNF423 | c.3654G>A p.P1218= (on ENST00000563137 / NM_001379286.1; = p.P1210= on NM_015069.4) | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs376719006, COSV52186601; called by muse, mutect2, varscan2
- FAT4 | c.12479+40del | Intron (DEL) | VAF 18/46 reads (39%) | catalogued as rs781278984; called by mutect2, varscan2
- VN1R10P | n.598C>T | RNA (SNP) | VAF 467/634 reads (74%) | catalogued as rs554344442; called by muse, varscan2
